CCDI case PBCHUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/a59a3253-1839-44c8-b77d-b1ac9afd5f93

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.9 years (705 days).

Biospecimens (2 samples)
- Sample 0DTVG8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTVGB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
